TARGET case TARGET-10-PASTSR — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3867ac20-e29c-45ec-b3bf-92cd47794652

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 10 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 10.4 years (3,813 days); Year of diagnosis: 2009; Days to last follow up: 2,482 days (6.8 years).
   Treatment given: Protocol identifier: AALL07P4.

Follow-up (1 entry)
- Days to follow up: 2,482 days (6.8 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,482; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 6.8 ×10³/µL.
- Day 8: Bone Marrow blast count 1%.
- Day 29: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (3 samples)
- Samples TARGET-10-PASTSR-09A, TARGET-10-PASTSR-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PASTSR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Dicentric_20230727.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2482
- WBC at Diagnosis: 6.8
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 1
- BMA Blasts Day 29: 2
- Karyotype: 45,XY,del(7)(q32q34),dic(9;12)(p13;p13)[5]/46,idem,+8[14]/46,XY[1]
- DNA Index: 1
- Cell of Origin: B-Precursor
